HCMI case HCM-BROD-1129-C56 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ca7bc7fd-6ce1-4d63-b935-804ff4d3abc2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Dead; Days to death: 1,431 days (3.9 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Classification of tumor: primary; Age at diagnosis: 61.4 years (22,421 days); AJCC staging edition: 8th; AJCC pathologic T: T3c; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Tumor grade: High Grade; Prior malignancy: no; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Neoadjuvant; Days to treatment start: 20 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,321 days (3.6 years); Days to treatment end: 1,379 days (3.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,321 days (3.6 years); Days to treatment end: 1,379 days (3.8 years).
   Recorded as not given: adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/6; ICD-10 code: C78.6; Tissue or organ of origin: Ovary; Site of resection or biopsy: Pleura, NOS; Classification of tumor: metastasis; Age at diagnosis: 63.3 years (23,129 days); Days to diagnosis: 708 days (1.9 years); Peritoneal fluid cytological status: Malignant; Sites of involvement: Fallopian Tube, NOS / Ascites / Liver.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Bevacizumab + Niraparib + Paclitaxel; Treatment intent type: Maintenance Therapy; Days to treatment start: 1,057 days (2.9 years); Days to treatment end: 1,168 days (3.2 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 1,431 days (3.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- BRCA1 mutation, nos (Targeted Sequencing): Positive; Pathogenicity: Pathogenic.
- BRCA2 mutation, nos (Targeted Sequencing): Negative.
- CA-125: 1265.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 156 cm; BMI: 28.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (2 samples)
- Sample HCM-BROD-1129-C56-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-1129-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
